Somatic mutation profile of tumor specimen TCGA-XF-A9T2-01A (aliquot TCGA-XF-A9T2-01A-11D-A42E-08) from TCGA case TCGA-XF-A9T2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 54.6 years (19,945 days).
Specimen TCGA-XF-A9T2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f41ab9d0-9b83-4991-beae-b016452c9098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T2-10A (Blood Derived Normal), aliquot TCGA-XF-A9T2-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52eac08a-4f58-4d6d-8020-748acba9d9e9

The open-access MAF lists 82 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Nonsense Mutation 7, 5'UTR 2, Frame Shift Ins 2, Frame Shift Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.4691G>A p.R1564Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs143045355; called by muse, mutect2, varscan2
- ABCC6 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as rs771770753, COSV52742444; called by muse, mutect2
- AHNAK2 | c.15105G>C p.K5035N | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV60911600; called by muse, mutect2, varscan2
- ANAPC5 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs566980298, COSV55842029; called by muse, mutect2, varscan2
- APLP1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as COSV55702523; called by muse, mutect2, varscan2
- BRINP2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64176578; called by muse, mutect2, varscan2
- CADPS | c.3868A>G p.I1290V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.891); catalogued as COSV51873145; called by mutect2, varscan2
- CCDC15 | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as rs1269732000, COSV61080939, COSV61083406; called by muse, mutect2, varscan2
- COL16A1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV54703275; called by muse, mutect2, varscan2
- CRTC3 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as rs1160190602, COSV99185996; called by muse, mutect2, varscan2
- CTNNB1 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV62695262, COSV62710424; called by muse, varscan2
- DDB1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); catalogued as rs373150519; called by muse, mutect2, varscan2
- DNAH10 | c.1258G>A p.V420M (on ENST00000409039; = p.V359M on NM_207437.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs1403614920, COSV68990676; called by muse, mutect2, varscan2
- DNAI4 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1268040709, COSV64021229; called by muse, mutect2, varscan2
- DYNC2H1 | c.12826G>T p.E4276* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100520007; called by muse, mutect2, varscan2
- EEF2 | c.1571T>A p.L524Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58578971; called by muse, mutect2, varscan2
- ENGASE | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV100286011; called by muse, mutect2, varscan2
- ERI3 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1330672738, COSV64830914; called by muse, mutect2, varscan2
- FAM149A | c.1547C>T p.S516F (on ENST00000356371 / NM_001367768.2; = p.S225F on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1178614656, COSV57026582; called by muse, mutect2, varscan2
- FAT3 | c.10323C>A p.D3441E | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV53092660; called by muse, mutect2, varscan2
- FBXW7 | c.1549G>A p.G517R (on ENST00000281708 / NM_001349798.2; = p.G437R on NM_018315.5) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55904471; called by muse, mutect2, varscan2
- GARRE1 | c.2905G>C p.D969H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV55097907; called by muse, mutect2, varscan2
- GPAM | c.558C>G p.I186M | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62080661; called by muse, mutect2, varscan2
- GSDMC | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52694426; called by muse, mutect2, varscan2
- IL16 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751326013, COSV57261942, COSV57267325; called by muse, mutect2, varscan2
- ITGAE | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV53991968; called by muse, mutect2, varscan2
- ITGAE | c.1490G>C p.R497T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1272576637, COSV53991977; called by muse, mutect2, varscan2
- KCNC4 | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV63925146, COSV63925381; called by muse, mutect2, varscan2
- KMT2D | c.13390C>T p.Q4464* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as CM105479, COSV56434505; called by muse, mutect2, varscan2
- MYH9 | c.5564G>A p.R1855Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs746568745, COSV53383960; called by muse, mutect2, varscan2
- N4BP3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs775757520, COSV51062168; called by muse, mutect2, varscan2
- NBR1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV57831575; called by muse, mutect2, varscan2
- PGRMC1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV54292124; called by muse, mutect2, varscan2
- PHRF1 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs374532392, COSV52753413; called by muse, varscan2
- POMT1 | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV61225475; called by muse, varscan2
- PRKCE | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); catalogued as COSV60315524; called by muse, mutect2, varscan2
- PRUNE1 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54846395, COSV54847763; called by muse, mutect2, varscan2
- RUNX1 | c.389G>T p.R130I (on ENST00000344691 / NM_001001890.3; = p.R157I on NM_001754.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55871984, COSV55885034; called by muse, varscan2
- SLC1A6 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs141949887, COSV55669198; called by muse, mutect2, varscan2
- SNTB1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV67324531, COSV67325390; called by muse, mutect2, varscan2
- SON | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV51654325; called by muse, mutect2, varscan2
- SPAG17 | c.444G>C p.K148N | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV104413215, COSV60455851; called by muse, mutect2, varscan2
- SPATA20 | c.1165C>A p.P389T (on ENST00000356488 / NM_001258372.1; = p.P405T on NM_022827.4) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.733); catalogued as COSV50066179; called by muse, mutect2, varscan2
- SPDYE3 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV60106940; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 23/31 reads (74%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- TAT | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs1316166172, COSV100587748; called by muse, mutect2, varscan2
- TIAL1 | c.816C>G p.C272W | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64843062; called by muse, mutect2, varscan2
- TLE6 | c.558G>A p.L186= (on ENST00000246112 / NM_001143986.2; = p.L63= on NM_024760.3) | Splice Region (SNP) | VAF 29/59 reads (49%) | catalogued as COSV55734934; called by muse, mutect2, varscan2
- TRPC7 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100726089; called by muse, mutect2
- TTC37 | c.3189G>A p.M1063I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV62454228; called by muse, mutect2, varscan2
- USF3 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV57071158; called by muse, mutect2, varscan2
- VAPA | c.569C>T p.S190L (on ENST00000400000 / NM_194434.3; = p.S235L on NM_003574.6) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV61297446; called by muse, mutect2, varscan2
- XRN1 | c.2836C>T p.H946Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.424); catalogued as COSV53809740; called by muse, mutect2
- DDX3X | c.1835dup p.S613Qfs*17 (on ENST00000399959; = p.S614Qfs*17 on NM_001356.5) | Frame Shift Ins (INS) | VAF 31/55 reads (56%) | called by mutect2, pindel, varscan2
- NSD1 | c.2117dup p.N706Kfs*12 | Frame Shift Ins (INS) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- RARS2 | c.15_24del p.F5Lfs*10 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- ACR | c.609C>T p.L203= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV53360496; called by muse, mutect2, varscan2
- ACSM6 | c.828G>C p.L276= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100498977, COSV58977938; called by muse, mutect2, varscan2
- ANKRD11 | c.2928G>A p.L976= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV56358206; called by muse, mutect2, varscan2
- DERA | c.855C>G p.L285= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs775988703, COSV70773987; called by muse, mutect2, varscan2
- FBXO24 | c.873G>C p.L291= (on ENST00000241071 / NM_033506.3; = p.L329= on NM_012172.5) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV53824840; called by muse, mutect2, varscan2
- FUT10 | c.1011C>T p.I337= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV59450565; called by muse, mutect2, varscan2
- GRIN2A | c.2547C>T p.F849= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as rs758351955, COSV58026969, COSV58050136; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF14 | c.162G>A p.L54= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs1178037660, COSV66260912; called by muse, mutect2, varscan2
- LAMA4 | c.4992C>T p.F1664= (on ENST00000230538 / NM_001105206.3; = p.F1657= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV57894516; called by muse, mutect2, varscan2
- MAN2A2 | c.66C>T p.L22= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV64637640; called by muse, mutect2, varscan2
- MRTO4 | c.126C>T p.I42= | Silent (SNP) | VAF 28/32 reads (88%) | catalogued as COSV57673651; called by muse, mutect2, varscan2
- MTCH1 | c.456G>A p.L152= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV65320186; called by muse, mutect2, varscan2
- NBR1 | c.681C>T p.V227= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs1407788524, COSV57831553, COSV57835490; called by muse, mutect2, varscan2
- OR52W1 | c.465G>A p.L155= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1176246009, COSV60950683; called by muse, mutect2, varscan2
- PHRF1 | c.678C>T p.F226= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52753392; called by muse, mutect2, varscan2
- PLPPR4 | c.1128C>T p.L376= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV64565062; called by muse, mutect2, varscan2
- PRR11 | c.1082G>A p.*361= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99231912; called by muse, mutect2, varscan2
- TECPR1 | c.2229C>T p.S743= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs371208080; called by muse, mutect2, varscan2
- TFEB | c.768G>A p.K256= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV57824222; called by muse, mutect2, varscan2
- TMEM186 | c.399G>C p.L133= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV51631234, COSV99191124; called by muse, mutect2, varscan2
- ZZEF1 | c.7695G>A p.Q2565= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV67556757; called by muse, mutect2, varscan2
- ERAL1 | chr17:28861430 C>T | 3'Flank (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- GSDMD | c.1_2dup p.M1Ifs*? | 5'UTR (INS) | VAF 6/18 reads (33%) | called by mutect2, pindel
- LOX | c.-1G>T | 5'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99140754; called by muse, mutect2, varscan2
